Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A65B, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A65B-01A (Primary Tumor).

FINAL DIAGNOSIS:**PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION -**

NO EVIDENCE OF NEOPLASIA IN THREE (3) LYMPH NODES EXAMINED.

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF NEOPLASIA IN TEN (10) LYMPH NODES EXAMINED.

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, MIXED SUBTYPES, GLEASON SCORE 4 + 5 = 9 (see comment).
- B. THE CARCINOMA INVOLVES BOTH RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 3 cm.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 35% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION IN THE REGION OF THE RIGHT POSTERIOR APEX (slides 3A, 3T) AND IN THE SOFT TISSUE SURROUNDING THE LEFT SEMINAL VESICLE.
- E. RIGHT SEMINAL VESICLE IS INVOLVED BY CARCINOMA (slide 3A).
- F. ALTHOUGH ALL MARGINS ARE NEGATIVE, THE CARCINOMA IS VERY CLOSE (LESS THAN 0.1 CM) IN THE REGION OF THE RIGHT POSTERIOR APEX IN AN AREA OF EXTRACAPSULAR EXTENSION (slide 3T).
- G. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. EXTENSIVE HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE (AJCC 7th EDITION): pT3b N0 MX.

COMMENT:

This poorly differentiated, high grade prostatic adenocarcinoma demonstrates areas with signet ring and cribriform types. In addition, very rare foci of Gleason pattern 3 adenocarcinoma, acinar type, are identified (slide 3M, 3O).

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA: PSA value: 5.8
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
Signet ring adenocarcinoma
PRIMARY GLEASON GRADE: 4
SECONDARY GLEASON GRADE: 5
GLEASON SUM SCORE: 9
GLEASON 4/5 PERCENTAGE: 95%
WEIGHT OF PROSTATE: 37.57gm
TUMOR SIZE: Maximum dimension: 3 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: > 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - multifocal
EXTRAPROSTATIC EXTENSION: Yes - Established (> 0.8mm)
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: Yes
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
LYMPH NODES EXAMINED: 13
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT3b
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

PATIENT HISTORY:

The patient is a year-old white male with a history of PSA value of 5.8. The patient also has a history of biopsy on his biopsy reveals: Poorly differentiated prostatic adenocarcinoma Gleason score 4+4 = 8 in the left base, left MID, left Apex, right apex, and right MID and Gleason score 4+5 = 9 in the right base.

PRE-OP DIAGNOSIS: Prostate cancer

POST-OP DIAGNOSIS: Same

PROCEDURE: Prostatectomy.

II/PA/Discrepancy		✓

Source: NCI Genomic Data Commons file dcb571f9-4f82-4c6d-8109-4fb76d37cda7 (TCGA-EJ-A65B.007E056B-1675-4639-9978-05C7EDEA1D74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).